Somatic mutation profile of tumor specimen ALCH-B2LT-TTP1-B (aliquot ALCH-B2LT-TTP1-B-1-0-D-A799-36) from ALCHEMIST case ALCH-B2LT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.9 years (23,700 days).
Specimen ALCH-B2LT-TTP1-B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01029d6e-5ce1-447a-a58a-7796cef13d21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2LT-NB1-A (Blood Derived Normal), aliquot ALCH-B2LT-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7bf4cc3c-3f75-4c72-871c-05379eeba663

The open-access MAF lists 471 somatic variants for this specimen: 331 protein-altering or splice-affecting, 86 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 276, Silent 86, Nonsense Mutation 22, Intron 20, Splice Site 15, 5'UTR 12, 3'UTR 8, Frame Shift Del 8, RNA 7, In Frame Del 5, 5'Flank 5, Splice Region 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 130/453 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960000, COSV67960068, COSV67960466; called by muse, mutect2, varscan2
- TP53 | c.487T>A p.Y163N | Missense Mutation (SNP) | VAF 75/188 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786203436, COSV52661160, COSV52676168, COSV52853225, COSV53025600; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACR | c.1205A>C p.D402A | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.007); catalogued as rs1327443849; called by mutect2, varscan2
- ADAMTS12 | c.3712G>A p.G1238R | Missense Mutation (SNP) | VAF 157/529 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV61280539; called by muse, mutect2, varscan2
- AEBP1 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 173/420 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.019); catalogued as rs375474488; called by muse, mutect2, varscan2
- AKAP8 | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs757004459; called by muse, mutect2, varscan2
- ANLN | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 82/214 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs528529344; called by muse, mutect2, varscan2
- AP5B1 | c.2053G>C p.E685Q | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV57503380; called by muse, mutect2, varscan2
- ATG16L1 | c.1031G>A p.R344H (on ENST00000392017 / NM_030803.7; = p.R325H on NM_017974.4) | Missense Mutation (SNP) | VAF 79/534 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436545472, COSV61465890; called by muse, mutect2, varscan2
- AUTS2 | c.980G>T p.R327L | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.357); catalogued as COSV61429562; called by muse, mutect2, varscan2
- AVPR1A | c.1049T>G p.F350C | Missense Mutation (SNP) | VAF 32/269 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as rs1360382211; called by muse, mutect2, varscan2
- BICD2 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs747158081, COSV63551199; called by muse, mutect2, varscan2
- BRINP2 | c.229del p.R77Gfs*21 | Frame Shift Del (DEL) | VAF 47/168 reads (28%) | catalogued as COSV64175951; called by mutect2, pindel, varscan2
- BRWD3 | c.1845G>C p.Q615H | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV64745355; called by muse, mutect2, varscan2
- BTBD8 | c.3907G>A p.D1303N (on ENST00000636805 / NM_001376131.1; = p.D790N on NM_015237.4) | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64885326; called by muse, mutect2
- C2orf78 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs763969172; called by mutect2, varscan2
- CAMK1D | c.809G>T p.C270F | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66614927; called by muse, mutect2, varscan2
- CCN4 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 66/138 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs529938783, COSV51533599; called by muse, varscan2
- CD1B | c.329A>T p.Y110F | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs746984607; called by muse, varscan2
- CD6 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 44/247 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs778444894, COSV57842489; called by muse, mutect2, varscan2
- CDKN2B | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 151/311 reads (49%) | catalogued as rs1263458730, CM155445; called by muse, mutect2, varscan2
- CETP | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 193/808 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs767437395; called by muse, mutect2, varscan2
- CHST13 | c.285C>A p.D95E | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.885); catalogued as rs866549861; called by muse, mutect2, varscan2
- CLDN20 | c.166T>C p.W56R | Missense Mutation (SNP) | VAF 44/225 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV65697794; called by muse, mutect2, varscan2
- COL1A2 | c.1651C>T p.P551S | Missense Mutation (SNP) | VAF 108/890 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.162); catalogued as rs267601643, COSV51956174; called by muse, mutect2, varscan2
- COL6A3 | c.3026T>C p.I1009T | Missense Mutation (SNP) | VAF 66/328 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV99796418; called by muse, mutect2, varscan2
- CPA6 | c.752G>C p.R251P | Missense Mutation (SNP) | VAF 85/259 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52719988; called by muse, mutect2, varscan2
- CSNK2A1 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53936118; called by muse, mutect2
- CSNK2A3 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 157/547 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57148071; called by muse, mutect2, varscan2
- CTNNA2 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 112/397 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV63557850; called by muse, mutect2, varscan2
- CYTIP | c.440T>C p.V147A | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV51632815; called by muse, mutect2, varscan2
- DICER1 | c.3289G>T p.G1097W | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100602593; called by muse, mutect2, varscan2
- DLG3 | c.1518C>T p.V506= (on ENST00000374360 / NM_021120.4; = p.V169= on NM_020730.3) | Splice Region (SNP) | VAF 47/153 reads (31%) | catalogued as rs758631454; called by muse, mutect2, varscan2
- DNAH12 | c.453C>A p.S151R | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV100244583; called by muse, mutect2, varscan2
- ERP29 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs751471173; called by muse, mutect2, varscan2
- F9 | c.735T>G p.N245K | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as CD961998; called by muse, mutect2, varscan2
- FAM135B | c.2819C>A p.T940K | Missense Mutation (SNP) | VAF 112/212 reads (53%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV52708278, COSV99421433; called by muse, mutect2, varscan2
- FAM189A1 | c.368C>A p.S123Y | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1357519420; called by muse, mutect2, varscan2
- FLG | c.1927A>G p.R643G | Missense Mutation (SNP) | VAF 94/1229 reads (8%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.879); catalogued as rs762662395; called by muse, mutect2
- FMN2 | c.2735C>G p.P912R | Missense Mutation (SNP) | VAF 66/113 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.9); catalogued as rs781539597, COSV60431541; called by muse, mutect2, varscan2
- FSTL5 | c.1735G>T p.G579W | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV60180355; called by muse, mutect2, varscan2
- GCK | c.1151C>A p.A384E | Missense Mutation (SNP) | VAF 177/413 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as CM096940, CM154282, COSV99789991; called by muse, mutect2, varscan2
- GEN1 | c.2056C>T p.Q686* | Nonsense Mutation (SNP) | VAF 24/92 reads (26%) | catalogued as rs748008372, COSV58057377; called by muse, mutect2, varscan2
- GJA8 | c.909G>C p.K303N | Missense Mutation (SNP) | VAF 126/306 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV53789142; called by mutect2, varscan2
- GRIA1 | c.2270+1G>T p.X757_splice | Splice Site (SNP) | VAF 30/60 reads (50%) | catalogued as COSV99602496; called by muse, varscan2
- GRK5 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 49/287 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs1381942896, COSV64866701; called by muse, mutect2, varscan2
- H4C12 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs530988823; called by muse, mutect2, varscan2
- HAND2 | c.441C>G p.Y147* | Nonsense Mutation (SNP) | VAF 149/438 reads (34%) | catalogued as COSV64019358; called by muse, mutect2, varscan2
- HLX | c.138C>G p.I46M | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV65045350; called by muse, mutect2, varscan2
- HOXB5 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53313754; called by muse, mutect2, varscan2
- HOXB6 | c.557C>T p.T186M | Missense Mutation (SNP) | VAF 59/523 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1446383437, COSV99494520; called by muse, mutect2, varscan2
- IGHV3-48 | c.53A>T p.Q18L | Missense Mutation (SNP) | VAF 92/221 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.119); catalogued as rs565016878; called by muse, mutect2, varscan2
- IKZF3 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 36/416 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs778371145, COSV53108210; called by muse, mutect2
- ILDR2 | c.679G>T p.D227Y | Missense Mutation (SNP) | VAF 192/627 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV54831405; called by muse, mutect2, varscan2
- JPH3 | c.1049A>G p.N350S | Missense Mutation (SNP) | VAF 80/301 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1332818006; called by muse, mutect2, varscan2
- KAT6B | c.2832C>G p.H944Q | Missense Mutation (SNP) | VAF 142/501 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.011); catalogued as rs764005007; called by muse, mutect2, varscan2
- KIR2DL3 | c.305G>C p.G102A | Missense Mutation (SNP) | VAF 51/565 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV60898578; called by muse, mutect2
- KRTAP10-5 | c.554C>G p.P185R | Missense Mutation (SNP) | VAF 111/764 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59956103; called by muse, mutect2, varscan2
- LDAH | c.418A>G p.I140V | Missense Mutation (SNP) | VAF 79/390 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.209); catalogued as rs763001302; called by muse, mutect2, varscan2
- LPA | c.3956C>G p.T1319S | Missense Mutation (SNP) | VAF 101/541 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.092); catalogued as COSV100306672; called by muse, mutect2, varscan2
- LPP | c.1456C>T p.R486W | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1331003393; called by muse, mutect2
- LZTR1 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 73/237 reads (31%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.019); catalogued as rs745476291; called by muse, mutect2, varscan2
- MAP3K21 | c.2408C>T p.S803F | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.87); catalogued as rs745464954; called by muse, mutect2, varscan2
- MGAT1 | c.83_85del p.F28del | In Frame Del (DEL) | VAF 34/262 reads (13%) | catalogued as rs758954674; called by pindel, varscan2
- MTF2 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 35/131 reads (27%) | catalogued as COSV64772045; called by muse, mutect2, varscan2
- MUC6 | c.3251C>A p.A1084D | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV70132348; called by muse, mutect2, varscan2
- MYO1A | c.1055G>T p.R352L | Missense Mutation (SNP) | VAF 561/1075 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100271041; called by muse, mutect2, varscan2
- NCOA7 | c.2699G>A p.R900Q | Missense Mutation (SNP) | VAF 165/440 reads (38%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as rs1377975566, COSV57660564; called by muse, mutect2, varscan2
- NKD1 | c.809C>A p.S270Y | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99194061; called by muse, mutect2, varscan2
- NLRP12 | c.2599C>T p.R867C | Missense Mutation (SNP) | VAF 250/667 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs149373778, COSV100145612; called by muse, varscan2
- NRG1 | c.1541C>A p.A514D (on ENST00000405005 / NM_013964.5; = p.A519D on NM_013956.5) | Missense Mutation (SNP) | VAF 44/286 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV55148518; called by muse, mutect2, varscan2
- NTSR1 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as rs1339021116, COSV65139079; called by muse, mutect2, varscan2
- OPTC | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 278/851 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs114751507, COSV65867226; called by muse, mutect2, varscan2
- OR10X1 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT tolerated (0.73); PolyPhen probably damaging (1); catalogued as COSV63767057, COSV63767735; called by muse, mutect2
- OR51F1 | c.266C>A p.T89K | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs766999466, COSV58579041; called by muse, mutect2, varscan2
- OR52N2 | c.464T>A p.V155E | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1445722741; called by muse, mutect2, varscan2
- OR52R1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 112/381 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100617769; called by muse, mutect2, varscan2
- OR52W1 | c.479T>C p.I160T | Missense Mutation (SNP) | VAF 157/507 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs774486080; called by muse, mutect2, varscan2
- OR5T1 | c.823A>C p.S275R | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV57302939; called by muse, mutect2, varscan2
- OR8K3 | c.682A>T p.M228L | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.075); catalogued as COSV57131358; called by muse, mutect2, varscan2
- OTOGL | c.5699C>G p.P1900R (on ENST00000547103; = p.P1891R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/336 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs867045153; called by muse, mutect2, varscan2
- PANX1 | c.205C>A p.P69T | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746605333, COSV57132983; called by muse, mutect2, varscan2
- PATE3 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs760066913; called by muse, mutect2, varscan2
- PCDHB10 | c.2077G>T p.V693L | Missense Mutation (SNP) | VAF 139/552 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.101); catalogued as rs200170483; called by muse, mutect2
- PCDHGB3 | c.1831G>C p.A611P | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99547728; called by muse, mutect2, varscan2
- PCLO | c.13991G>C p.S4664T | Missense Mutation (SNP) | VAF 121/583 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100428944; called by muse, mutect2, varscan2
- PHTF2 | c.1810C>T p.H604Y (on ENST00000248550 / NM_001366089.1; = p.H566Y on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1036001283, COSV50325707; called by muse, mutect2, varscan2
- PIWIL3 | c.2444A>G p.Y815C | Missense Mutation (SNP) | VAF 88/187 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771259692; called by muse, mutect2, varscan2
- PKD1 | c.11978C>G p.S3993W (on ENST00000262304 / NM_001009944.3; = p.S3992W on NM_000296.4) | Missense Mutation (SNP) | VAF 104/303 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV51914083; called by muse, mutect2, varscan2
- PLEC | c.10483G>A p.A3495T (on ENST00000322810 / NM_201380.4; = p.A3385T on NM_000445.5) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs533543775, COSV100509528; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POM121L12 | c.633G>C p.Q211H | Missense Mutation (SNP) | VAF 88/217 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV68692616; called by muse, mutect2, varscan2
- PPIA | c.24C>G p.F8L | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.072); catalogued as COSV63534338; called by muse, mutect2, varscan2
- PPL | c.68C>G p.S23C | Missense Mutation (SNP) | VAF 107/286 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771567112; called by muse, mutect2, varscan2
- PRAMEF4 | c.550T>C p.C184R | Missense Mutation (SNP) | VAF 51/751 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs914144419; called by muse, mutect2, varscan2
- PROKR1 | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 79/287 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs755325729; called by muse, mutect2, varscan2
- PYCR3 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 96/508 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs761865026; called by muse, mutect2, varscan2
- RBM20 | c.2588C>T p.P863L | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.691); catalogued as rs794729153; called by muse, mutect2, varscan2
- RBM44 | c.227C>T p.S76L (on ENST00000611254; = p.S710L on NM_001080504.2) | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as rs373599531; called by muse, mutect2, varscan2
- REST | c.1219C>G p.H407D | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100470842; called by muse, mutect2, varscan2
- RIMBP3B | c.4595C>T p.P1532L | Missense Mutation (SNP) | VAF 70/1048 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as rs548074561, COSV100775094, COSV63115788; called by muse, mutect2
- RIPOR2 | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52428089; called by muse, mutect2, varscan2
- RPF1 | c.770A>G p.H257R | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.302); catalogued as COSV65705982; called by muse, mutect2, varscan2
- SCN11A | c.5170A>G p.I1724V | Missense Mutation (SNP) | VAF 105/272 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs912580113; called by muse, mutect2, varscan2
- SEPTIN12 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 117/324 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99190857; called by muse, mutect2, varscan2
- SLC5A2 | c.1250C>T p.A417V | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs966721203; called by muse, mutect2, varscan2
- SOHLH2 | c.376A>T p.M126L | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV58522561; called by muse, mutect2, varscan2
- SORCS3 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs373150688; called by muse, mutect2, varscan2
- SOX1 | c.826C>T p.L276F | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.346); catalogued as COSV58380114; called by muse, mutect2, varscan2
- SPRED1 | c.423+1G>T p.X141_splice | Splice Site (SNP) | VAF 75/255 reads (29%) | catalogued as CS075236; called by muse, mutect2, varscan2
- SVIL | c.2698C>T p.L900F (on ENST00000355867 / NM_021738.3; = p.L474F on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/404 reads (13%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.052); catalogued as rs750778684, COSV100881390; called by muse, mutect2, varscan2
- SYCP1 | c.2296C>A p.Q766K | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV65697522; called by muse, mutect2, varscan2
- TAB2 | c.1764+9_1764+10del | Splice Region (DEL) | VAF 33/247 reads (13%) | catalogued as rs757967348; called by mutect2, pindel, varscan2
- TCHHL1 | c.1348G>C p.E450Q | Missense Mutation (SNP) | VAF 31/426 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.063); catalogued as COSV100916584; called by muse, mutect2
- TCHHL1 | c.836G>A p.R279K | Missense Mutation (SNP) | VAF 56/424 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as rs762722906; called by muse, mutect2, varscan2
- TCTE1 | c.756C>A p.C252* | Nonsense Mutation (SNP) | VAF 33/253 reads (13%) | catalogued as rs541645736, COSV101025291; called by muse, mutect2, varscan2
- TEX37 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.067); catalogued as rs201634174; called by muse, mutect2, varscan2
- TFCP2 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV56931593, COSV99227388; called by muse, mutect2, varscan2
- TIMELESS | c.2776C>T p.R926* | Nonsense Mutation (SNP) | VAF 87/204 reads (43%) | catalogued as rs756089942, COSV57511589; called by muse, mutect2, varscan2
- TOX4 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 99/279 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs777393283, COSV52968643; called by muse, mutect2, varscan2
- TRIM51 | c.992G>T p.W331L | Missense Mutation (SNP) | VAF 137/483 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs767532374; called by muse, mutect2, varscan2
- TRIM72 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 57/153 reads (37%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.727); catalogued as rs778233584; called by muse, mutect2, varscan2
- TRPM8 | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61221378; called by muse, mutect2, varscan2
- TTLL6 | c.1762-2A>C p.X588_splice (on ENST00000393382 / NM_001130918.3; = p.X281_splice on NM_173623.3) | Splice Site (SNP) | VAF 63/191 reads (33%) | catalogued as COSV64977385; called by muse, mutect2, varscan2
- TTN | c.23135C>A p.P7712H (on ENST00000591111; = p.P6785H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 159/578 reads (28%) | PolyPhen possibly damaging (0.518); catalogued as COSV100595673; called by muse, mutect2, varscan2
- U2AF2 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs372124094; called by muse, mutect2, varscan2
- VSIG2 | c.316C>G p.L106V | Missense Mutation (SNP) | VAF 220/665 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.832); catalogued as COSV52519461; called by muse, mutect2, varscan2
- WEE1 | c.1020-1G>A p.X340_splice | Splice Site (SNP) | VAF 38/128 reads (30%) | catalogued as COSV100219590; called by muse, mutect2
- XKR4 | c.330G>T p.W110C | Missense Mutation (SNP) | VAF 63/208 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); catalogued as COSV100532057; called by muse, mutect2, varscan2
- ZFC3H1 | c.1988A>T p.H663L | Missense Mutation (SNP) | VAF 24/253 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV66432107; called by muse, mutect2, varscan2
- ZFHX4 | c.10552del p.L3518Ffs*6 | Frame Shift Del (DEL) | VAF 98/410 reads (24%) | catalogued as COSV50781668; called by pindel, varscan2
- ZNF106 | c.1240C>A p.L414I | Missense Mutation (SNP) | VAF 128/353 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as COSV55513677, COSV55514237; called by muse, mutect2, varscan2
- ZNF391 | c.781A>G p.I261V | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.096); catalogued as COSV99772606; called by muse, mutect2, varscan2
- ZNF692 | c.53G>C p.R18P | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs779006138; called by muse, mutect2, varscan2
- ZNF735 | c.950G>T p.R317I | Missense Mutation (SNP) | VAF 72/428 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.024); catalogued as rs762121895, COSV70036128; called by muse, mutect2, varscan2
- ZNF804A | c.359T>A p.L120Q | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100166002; called by muse, mutect2, varscan2
- AASS | c.2742A>T p.E914D | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ABCA3 | c.3292T>A p.F1098I | Missense Mutation (SNP) | VAF 95/328 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- ACP4 | c.479C>A p.P160H | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ADAM12 | c.2691C>A p.H897Q | Missense Mutation (SNP) | VAF 89/285 reads (31%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- ADAM33 | c.1390G>C p.V464L | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAM33 | c.1057C>A p.L353I | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ADAMTS12 | c.4111G>C p.G1371R | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ADGRG5 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRL2 | c.367C>T p.L123F | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ALG8 | c.1207G>C p.A403P | Missense Mutation (SNP) | VAF 70/262 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APOB | c.11101C>T p.H3701Y | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AQR | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ARHGAP32 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 139/437 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- ARMC3 | c.2485C>A p.L829M | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ASTN1 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 49/200 reads (25%) | called by muse, mutect2, varscan2
- ATG2A | c.1617C>T p.I539= | Splice Region (SNP) | VAF 29/196 reads (15%) | called by muse, mutect2, varscan2
- ATP11B | c.254C>A p.T85N | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ATP11B | c.256A>G p.S86G | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ATP2A3 | c.118+1G>A p.X40_splice | Splice Site (SNP) | VAF 29/60 reads (48%) | called by muse, mutect2, varscan2
- ATP8A2 | c.1514C>A p.A505D | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- ATRX | c.3425C>G p.S1142* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- BMP6 | c.309G>T p.Q103H | Missense Mutation (SNP) | VAF 81/250 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- BNIP5 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 140/428 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- BRF1 | c.820C>A p.Q274K | Missense Mutation (SNP) | VAF 134/524 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C11orf95 | c.1404_1418del p.G469_Q473del | In Frame Del (DEL) | VAF 23/67 reads (34%) | called by mutect2, pindel, varscan2
- C20orf194 | c.2556_2564del p.T853_G855del | In Frame Del (DEL) | VAF 25/180 reads (14%) | called by mutect2, pindel, varscan2
- C8orf33 | c.62G>T p.C21F | Missense Mutation (SNP) | VAF 133/270 reads (49%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- CACNA1G | c.1730C>G p.S577C | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- CCDC83 | c.995A>G p.K332R (on ENST00000342404 / NM_001286159.2; = p.K363R on NM_173556.5) | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- CD1C | c.271T>C p.Y91H | Missense Mutation (SNP) | VAF 41/331 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- CDH15 | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 88/268 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELF1 | c.199dup p.Y67Lfs*4 | Frame Shift Ins (INS) | VAF 18/200 reads (9%) | called by mutect2, pindel
- CHD1 | c.1890A>C p.L630F | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CNTNAP5 | c.356A>T p.Q119L | Missense Mutation (SNP) | VAF 49/454 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- COL9A1 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 132/777 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRACD | c.2966T>C p.L989P | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- CSMD1 | c.10076G>T p.W3359L (on ENST00000520002; = p.W3358L on NM_033225.6) | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CUL3 | c.1900C>G p.L634V | Missense Mutation (SNP) | VAF 24/249 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- CYP11B1 | c.637G>T p.G213C | Missense Mutation (SNP) | VAF 369/860 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- DAB1 | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 76/243 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- DHRS11 | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 53/377 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- DNAH14 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 29/207 reads (14%) | called by muse, mutect2, varscan2
- DNAJC11 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 106/318 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.031); called by muse, varscan2
- DNAJC22 | c.908T>A p.V303D | Missense Mutation (SNP) | VAF 58/432 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- DOCK10 | c.1829T>G p.M610R | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DSCAML1 | c.1184C>T p.S395F (on ENST00000321322; = p.S335F on NM_020693.4) | Missense Mutation (SNP) | VAF 112/330 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- E2F6 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 70/196 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- E2F7 | c.1031G>T p.S344I | Missense Mutation (SNP) | VAF 59/342 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPC1 | c.2413_2428del p.S805Qfs*14 | Frame Shift Del (DEL) | VAF 15/111 reads (14%) | called by mutect2, pindel, varscan2
- EPHA2 | c.153+2del p.X51_splice | Splice Site (DEL) | VAF 37/208 reads (18%) | called by mutect2, pindel, varscan2
- EVI5 | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EYA1 | c.1360G>T p.G454C | Missense Mutation (SNP) | VAF 49/520 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2
- FAM135A | c.3673G>A p.E1225K (on ENST00000370479 / NM_001351599.1; = p.E1012K on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- FAM166A | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAM216B | c.256C>G p.L86V | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0); called by mutect2, varscan2
- FAT3 | c.6435C>A p.F2145L | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FBF1 | c.114G>T p.K38N (on ENST00000586717; = p.K52N on NM_001319193.1) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- FLI1 | c.1030G>C p.D344H | Missense Mutation (SNP) | VAF 131/393 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMNL1 | c.176A>G p.Y59C | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRY | c.237A>T p.E79D | Missense Mutation (SNP) | VAF 184/469 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- GAB4 | c.1476+2T>C p.X492_splice | Splice Site (SNP) | VAF 16/99 reads (16%) | called by muse, mutect2, varscan2
- GABRA4 | c.1582G>T p.V528F | Missense Mutation (SNP) | VAF 46/257 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- GALNT9 | c.897G>T p.W299C | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- GALNT9 | c.896G>A p.W299* | Nonsense Mutation (SNP) | VAF 25/186 reads (13%) | called by muse, mutect2, varscan2
- GBP7 | c.1265C>G p.S422* | Nonsense Mutation (SNP) | VAF 78/485 reads (16%) | called by muse, mutect2, varscan2
- GCFC2 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- GH2 | c.637G>T p.G213C | Missense Mutation (SNP) | VAF 152/434 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GLI1 | c.572G>T p.R191L | Missense Mutation (SNP) | VAF 146/294 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLI4 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- GRM5 | c.911+2T>A p.X304_splice | Splice Site (SNP) | VAF 69/243 reads (28%) | called by muse, mutect2, varscan2
- GRXCR1 | c.371C>A p.T124N | Missense Mutation (SNP) | VAF 74/337 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- H2BC4 | c.44C>G p.S15C | Missense Mutation (SNP) | VAF 23/246 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.728); called by muse, mutect2
- HERC2 | c.5845G>T p.E1949* | Nonsense Mutation (SNP) | VAF 102/235 reads (43%) | called by muse, mutect2, varscan2
- HKDC1 | c.1804T>A p.S602T | Missense Mutation (SNP) | VAF 82/305 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPA9 | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 165/372 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- HSPBP1 | c.820G>T p.V274F | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- IFITM1 | c.86G>C p.S29T | Missense Mutation (SNP) | VAF 93/305 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- IGF1R | c.1248-2A>T p.X416_splice | Splice Site (SNP) | VAF 179/403 reads (44%) | called by muse, mutect2, varscan2
- IL1RL1 | c.1639A>G p.S547G | Missense Mutation (SNP) | VAF 62/114 reads (54%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- IL32 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INO80B | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.756); called by muse, varscan2
- ITGA10 | c.1048C>G p.L350V | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- ITGAD | c.2190C>G p.H730Q | Missense Mutation (SNP) | VAF 69/205 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- ITPRIPL1 | c.1498C>A p.L500M (on ENST00000439118 / NM_001008949.3; = p.L508M on NM_178495.6) | Missense Mutation (SNP) | VAF 38/514 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- JPH1 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- KIAA0586 | c.3317C>T p.T1106I (on ENST00000619416 / NM_001244190.2; = p.T1045I on NM_014749.5) | Missense Mutation (SNP) | VAF 111/357 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KIAA1755 | c.629A>G p.D210G | Missense Mutation (SNP) | VAF 47/258 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KIF4A | c.1808A>G p.Q603R | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRIT2 | c.959T>C p.V320A | Missense Mutation (SNP) | VAF 109/220 reads (50%) | SIFT tolerated (0.76); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRRC53 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- LTBP1 | c.3388T>C p.C1130R (on ENST00000404816 / NM_206943.4; = p.C804R on NM_000627.4) | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MACF1 | c.7012C>T p.Q2338* | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- MACROD2 | c.271+1G>T p.X91_splice | Splice Site (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- MALRD1 | c.3171C>A p.C1057* | Nonsense Mutation (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- MAP2K7 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCM9 | c.2792T>G p.L931R | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MCM9 | c.2285C>G p.S762C | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.093); called by muse, mutect2
- MFAP4 | c.9del p.L4Sfs*69 | Frame Shift Del (DEL) | VAF 46/138 reads (33%) | called by mutect2, pindel, varscan2
- MLKL | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 153/414 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MPDZ | c.3041G>A p.G1014D | Missense Mutation (SNP) | VAF 88/206 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MRPS26 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 47/247 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- MT3 | c.41G>A p.C14Y | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MUC16 | c.7303T>A p.Y2435N | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- MYH15 | c.45G>T p.W15C | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- MYH15 | c.44G>T p.W15L | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- MYLK2 | c.889G>C p.G297R | Missense Mutation (SNP) | VAF 353/719 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYT1 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 128/484 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- NACAD | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- NALCN | c.4432G>T p.D1478Y | Missense Mutation (SNP) | VAF 21/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NAT2 | c.173A>G p.H58R | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NCEH1 | c.736C>T p.Q246* (on ENST00000538775; = p.Q206* on NM_020792.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 17/133 reads (13%) | called by muse, mutect2, varscan2
- NDST1 | c.1921G>C p.E641Q | Missense Mutation (SNP) | VAF 174/442 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEB | c.11415G>C p.K3805N | Missense Mutation (SNP) | VAF 54/392 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NFIB | c.1154del p.P385Qfs*9 | Frame Shift Del (DEL) | VAF 137/357 reads (38%) | called by mutect2, pindel, varscan2
- NOP2 | c.238+5G>T | Splice Region (SNP) | VAF 31/143 reads (22%) | called by muse, mutect2, varscan2
- NPNT | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- NSD1 | c.6618_6659del p.D2206_R2219del | In Frame Del (DEL) | VAF 66/558 reads (12%) | called by mutect2, pindel
- NTNG1 | c.247-2A>G p.X83_splice | Splice Site (SNP) | VAF 24/66 reads (36%) | called by muse, mutect2, varscan2
- NUDCD1 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- OMA1 | c.976G>T p.G326C | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR14C36 | c.287T>C p.V96A | Missense Mutation (SNP) | VAF 40/484 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- OR2T12 | c.303C>G p.F101L | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT tolerated (0.91); PolyPhen benign (0.003); called by mutect2, varscan2
- OR2T35 | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 170/377 reads (45%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- OR4S1 | c.29T>G p.F10C | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- OR5D14 | c.763G>T p.G255W | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- OR5D14 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); called by mutect2, varscan2
- PARP10 | c.2608G>T p.E870* | Nonsense Mutation (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
- PDE4DIP | c.3232G>T p.E1078* | Nonsense Mutation (SNP) | VAF 38/452 reads (8%) | called by muse, mutect2
- PDE6B | c.722G>A p.W241* | Nonsense Mutation (SNP) | VAF 55/327 reads (17%) | called by muse, mutect2, varscan2
- PDZD2 | c.1683G>C p.K561N | Missense Mutation (SNP) | VAF 129/512 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- PHACTR1 | c.754G>T p.G252W | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PHF8 | c.2771C>T p.A924V (on ENST00000357988 / NM_001184896.1; = p.A888V on NM_015107.3) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PLCL1 | c.1803A>T p.E601D | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PPFIA3 | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- PPID | c.241A>T p.M81L | Missense Mutation (SNP) | VAF 93/266 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- PRKDC | c.3523C>T p.H1175Y | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PROS1 | c.161T>C p.L54P | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB19 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 94/450 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RABGAP1L | c.177G>T p.M59I | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RBM12B | c.2816A>G p.N939S | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- RBM47 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- RECK | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- RELN | c.3236G>T p.W1079L | Missense Mutation (SNP) | VAF 90/1114 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- RIMS2 | c.972del p.R325Efs*20 (on ENST00000666250 / NM_001348490.2; = p.R133Efs*20 on NM_014677.5 and 7 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 42/410 reads (10%) | called by mutect2, pindel, varscan2
- RPL3L | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 64/210 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- RXFP1 | c.767G>C p.G256A | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- SALL1 | c.2143C>G p.L715V | Missense Mutation (SNP) | VAF 74/233 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SCARF2 | c.204G>C p.W68C | Missense Mutation (SNP) | VAF 238/486 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- SCN11A | c.1502T>C p.L501P | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SCRT1 | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- SDK2 | c.4648A>G p.R1550G | Missense Mutation (SNP) | VAF 47/313 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- SEC31A | c.1246C>G p.Q416E | Missense Mutation (SNP) | VAF 126/410 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SEMA3C | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SEMA6D | c.3007A>G p.T1003A (on ENST00000316364 / NM_153618.2; = p.T941A on NM_020858.2) | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERTAD4 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SH2B2 | c.367G>T p.V123L | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SI | c.4599T>A p.F1533L | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SIAE | c.697A>T p.K233* | Nonsense Mutation (SNP) | VAF 56/368 reads (15%) | called by muse, mutect2, varscan2
- SLC26A5 | c.819G>T p.L273F | Missense Mutation (SNP) | VAF 58/539 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- SLC35C1 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 17/107 reads (16%) | called by muse, mutect2
- SLC44A5 | c.1507del p.T503Lfs*14 | Frame Shift Del (DEL) | VAF 44/149 reads (30%) | called by mutect2, pindel, varscan2
- SLC7A2 | c.1728G>T p.M576I (on ENST00000494857 / NM_001370338.1; = p.M615I on NM_003046.6) | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLFN11 | c.2458G>C p.E820Q | Missense Mutation (SNP) | VAF 129/420 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SMARCA4 | c.2275-2A>G p.X759_splice | Splice Site (SNP) | VAF 143/387 reads (37%) | called by muse, mutect2, varscan2
- SMG8 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMG9 | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 162/214 reads (76%) | SIFT tolerated (0.07); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- SPSB4 | c.695-1G>A p.X232_splice | Splice Site (SNP) | VAF 42/160 reads (26%) | called by muse, mutect2, varscan2
- ST7L | c.623-2A>G p.X208_splice | Splice Site (SNP) | VAF 13/112 reads (12%) | called by muse, mutect2, varscan2
- STIM1 | c.178G>C p.D60H | Missense Mutation (SNP) | VAF 192/576 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- STRIP2 | c.1248G>C p.K416N | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- TBC1D4 | c.1732-1G>T p.X578_splice | Splice Site (SNP) | VAF 69/219 reads (32%) | called by muse, mutect2, varscan2
- TBRG4 | c.1855G>A p.D619N | Missense Mutation (SNP) | VAF 139/342 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- THEMIS | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 40/500 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMC1 | c.943T>C p.W315R | Missense Mutation (SNP) | VAF 158/325 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TMC1 | c.944G>T p.W315L | Missense Mutation (SNP) | VAF 156/325 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- TMEM72 | c.665T>C p.V222A | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- TNK2 | c.1251G>C p.E417D | Missense Mutation (SNP) | VAF 30/233 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- TTN | c.36061G>A p.G12021R (on ENST00000591111; = p.G4597R on NM_003319.4) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBAP2L | c.1141C>A p.Q381K | Missense Mutation (SNP) | VAF 56/545 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- UBXN1 | c.33C>G p.I11M | Missense Mutation (SNP) | VAF 63/182 reads (35%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- UNC13A | c.4846G>C p.E1616Q | Missense Mutation (SNP) | VAF 159/305 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USF2 | c.232A>T p.T78S | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2
- USP54 | c.3663_3667del p.S1221Rfs*22 | Frame Shift Del (DEL) | VAF 90/256 reads (35%) | called by mutect2, pindel, varscan2
- UTP11 | c.16C>G p.R6G | Missense Mutation (SNP) | VAF 112/411 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- VPS13B | c.2733T>G p.N911K | Missense Mutation (SNP) | VAF 32/251 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- VPS35L | c.359_370del p.K120_E123del | In Frame Del (DEL) | VAF 29/315 reads (9%) | called by mutect2, pindel
- YLPM1 | c.2632A>T p.K878* | Nonsense Mutation (SNP) | VAF 65/359 reads (18%) | called by muse, mutect2, varscan2
- ZAN | c.5299A>T p.S1767C | Missense Mutation (SNP) | VAF 104/216 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZFHX4 | c.6485T>C p.M2162T | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ZFP36L2 | c.161G>T p.R54L | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZFYVE9 | c.716G>T p.S239I | Missense Mutation (SNP) | VAF 89/283 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF212 | c.893T>G p.L298R | Missense Mutation (SNP) | VAF 131/326 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF439 | c.544G>T p.G182* | Nonsense Mutation (SNP) | VAF 62/188 reads (33%) | called by muse, mutect2, varscan2
- ZNF729 | c.2171C>T p.S724L | Missense Mutation (SNP) | VAF 123/326 reads (38%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.731); called by muse, varscan2
- ZNF729 | c.2290A>T p.R764W | Missense Mutation (SNP) | VAF 101/271 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- ZNF787 | c.1057A>G p.S353G | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AP2B1 | c.600C>T p.N200= | Silent (SNP) | VAF 104/377 reads (28%) | catalogued as rs776542260; called by muse, mutect2, varscan2
- AQP7 | c.685C>A p.R229= | Silent (SNP) | VAF 115/231 reads (50%) | catalogued as COSV53035946; called by muse, mutect2, varscan2
- ASTN2 | c.3987C>G p.A1329= (on ENST00000313400 / NM_001365069.1; = p.A1278= on NM_014010.5) | Silent (SNP) | VAF 122/261 reads (47%) | catalogued as COSV56006117; called by muse, mutect2, varscan2
- C1orf94 | c.1506G>A p.L502= (on ENST00000488417 / NM_001134734.2; = p.L312= on NM_032884.5) | Silent (SNP) | VAF 69/221 reads (31%) | catalogued as rs757924582; called by muse, mutect2, varscan2
- CAMK2B | c.1410C>G p.L470= | Silent (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- CCDC93 | c.1827G>T p.V609= | Silent (SNP) | VAF 117/205 reads (57%) | called by muse, mutect2, varscan2
- CEL | c.1569G>A p.E523= (on ENST00000673714; = p.E520= on NM_001807.6) | Silent (SNP) | VAF 284/676 reads (42%) | catalogued as rs749367092; called by muse, mutect2, varscan2
- CELA3B | c.18C>G p.L6= | Silent (SNP) | VAF 118/426 reads (28%) | called by muse, mutect2, varscan2
- CEP192 | c.6048G>A p.V2016= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as rs1382884292; called by muse, mutect2
- CFAP91 | c.345C>G p.L115= | Silent (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- COL5A3 | c.2430C>T p.P810= | Silent (SNP) | VAF 29/74 reads (39%) | called by muse, mutect2, varscan2
- DES | c.357C>T p.F119= | Silent (SNP) | VAF 72/492 reads (15%) | catalogued as rs1156903614, COSV64660271; called by muse, mutect2, varscan2
- DGKG | c.324G>A p.Q108= | Silent (SNP) | VAF 30/443 reads (7%) | called by muse, mutect2
- DICER1 | c.1533T>C p.H511= | Silent (SNP) | VAF 24/297 reads (8%) | catalogued as rs1555372906, CD154595; ClinVar: likely benign; called by muse, mutect2
- DNAJB9 | c.633A>T p.G211= | Silent (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- DPP10 | c.1188A>T p.G396= | Silent (SNP) | VAF 25/288 reads (9%) | called by muse, mutect2
- DPPA4 | c.774A>T p.P258= | Silent (SNP) | VAF 96/360 reads (27%) | called by muse, mutect2, varscan2
- EMX1 | c.597C>T p.F199= | Silent (SNP) | VAF 110/374 reads (29%) | called by muse, mutect2, varscan2
- ESRP2 | c.969C>T p.G323= (on ENST00000565858 / NM_001365264.1; = p.G313= on NM_024939.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as rs750416698; called by muse, mutect2, varscan2
- EYS | c.15A>T p.S5= | Silent (SNP) | VAF 41/182 reads (23%) | called by muse, mutect2, varscan2
- FAT2 | c.213C>T p.Y71= | Silent (SNP) | VAF 46/120 reads (38%) | called by muse, mutect2, varscan2
- FBXO42 | c.1878A>T p.P626= | Silent (SNP) | VAF 120/375 reads (32%) | called by muse, mutect2, varscan2
- FGF23 | c.750C>T p.F250= | Silent (SNP) | VAF 31/180 reads (17%) | called by muse, mutect2, varscan2
- FMN2 | c.3111C>T p.P1037= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs71297737; called by muse, varscan2
- FOXL1 | c.174C>T p.I58= | Silent (SNP) | VAF 67/488 reads (14%) | catalogued as COSV100206230, COSV57213736; called by muse, mutect2, varscan2
- GH2 | c.636G>A p.E212= | Silent (SNP) | VAF 156/444 reads (35%) | catalogued as rs1336981211; called by muse, mutect2, varscan2
- GRXCR1 | c.372C>A p.T124= | Silent (SNP) | VAF 75/339 reads (22%) | called by muse, mutect2, varscan2
- GUCY1A2 | c.294G>C p.T98= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs542771467; called by muse, mutect2, varscan2
- HELZ | c.216T>C p.N72= | Silent (SNP) | VAF 37/240 reads (15%) | called by muse, mutect2, varscan2
- HGF | c.336T>C p.F112= | Silent (SNP) | VAF 49/248 reads (20%) | called by muse, mutect2, varscan2
- HINT3 | c.159C>T p.I53= | Silent (SNP) | VAF 192/524 reads (37%) | called by muse, mutect2, varscan2
- IL12RB2 | c.99G>A p.V33= | Silent (SNP) | VAF 91/310 reads (29%) | called by muse, mutect2, varscan2
- IL17REL | c.570G>A p.A190= | Silent (SNP) | VAF 131/232 reads (56%) | catalogued as COSV58008465; called by muse, mutect2, varscan2
- KANSL1L | c.342T>C p.Y114= | Silent (SNP) | VAF 34/219 reads (16%) | called by muse, mutect2, varscan2
- KCNJ1 | c.930C>A p.V310= | Silent (SNP) | VAF 108/361 reads (30%) | called by muse, mutect2, varscan2
- KCNT2 | c.2517A>C p.L839= | Silent (SNP) | VAF 41/256 reads (16%) | called by muse, mutect2, varscan2
- KIF13B | c.159G>A p.P53= | Silent (SNP) | VAF 47/266 reads (18%) | catalogued as rs371957021; called by muse, mutect2, varscan2
- KLHL20 | c.936A>G p.K312= | Silent (SNP) | VAF 34/269 reads (13%) | called by muse, mutect2, varscan2
- KMT2A | c.729G>A p.E243= | Silent (SNP) | VAF 31/133 reads (23%) | called by muse, mutect2, varscan2
- LNX2 | c.1200G>T p.P400= | Silent (SNP) | VAF 65/155 reads (42%) | catalogued as rs377695945, COSV60335185; called by muse, mutect2, varscan2
- LOX | c.375C>T p.F125= | Silent (SNP) | VAF 36/132 reads (27%) | catalogued as rs1424480772; called by muse, mutect2, varscan2
- LYPD3 | c.882C>T p.P294= | Silent (SNP) | VAF 388/544 reads (71%) | called by muse, mutect2, varscan2
- MIB2 | c.2694C>G p.L898= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as rs551860185; called by muse, mutect2, varscan2
- MINDY4 | c.2085G>A p.E695= | Silent (SNP) | VAF 35/207 reads (17%) | called by muse, mutect2, varscan2
- MIPOL1 | c.72G>C p.T24= | Silent (SNP) | VAF 80/242 reads (33%) | called by muse, mutect2, varscan2
- MRPL3 | c.702G>T p.T234= | Silent (SNP) | VAF 38/295 reads (13%) | called by muse, mutect2, varscan2
- MRPL39 | c.54C>G p.P18= | Silent (SNP) | VAF 35/222 reads (16%) | catalogued as COSV56261257; called by muse, mutect2, varscan2
- MX2 | c.1890G>A p.L630= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- NALCN | c.4431G>A p.V1477= | Silent (SNP) | VAF 22/232 reads (9%) | called by muse, mutect2
- NANP | c.607T>C p.L203= | Silent (SNP) | VAF 50/300 reads (17%) | called by muse, mutect2, varscan2
- NME8 | c.403T>C p.L135= | Silent (SNP) | VAF 78/231 reads (34%) | called by muse, mutect2, varscan2
- NUP133 | c.1204C>T p.L402= | Silent (SNP) | VAF 15/118 reads (13%) | called by muse, mutect2, varscan2
- OCA2 | c.1233T>A p.A411= | Silent (SNP) | VAF 66/168 reads (39%) | called by muse, varscan2
- OR2AG1 | c.864C>T p.L288= | Silent (SNP) | VAF 56/208 reads (27%) | called by muse, mutect2, varscan2
- OR52L1 | c.339C>T p.I113= | Silent (SNP) | VAF 79/462 reads (17%) | catalogued as rs376543359, COSV100176063; called by muse, mutect2, varscan2
- OR5H2 | c.183C>T p.H61= | Silent (SNP) | VAF 15/138 reads (11%) | catalogued as rs1163328675; called by muse, mutect2, varscan2
- OTOG | c.7902C>A p.P2634= | Silent (SNP) | VAF 44/247 reads (18%) | called by muse, mutect2, varscan2
- PCDHA1 | c.879C>T p.F293= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV65374411, COSV65377378; called by muse, mutect2, varscan2
- PDE7B | c.1284C>T p.G428= | Silent (SNP) | VAF 91/556 reads (16%) | called by muse, mutect2, varscan2
- PEG3 | c.3087G>T p.A1029= | Silent (SNP) | VAF 39/110 reads (35%) | called by muse, mutect2, varscan2
- PHRF1 | c.2499C>T p.S833= (on ENST00000264555 / NM_001286581.2; = p.S832= on NM_020901.4) | Silent (SNP) | VAF 17/142 reads (12%) | catalogued as rs372302891; called by muse, mutect2, varscan2
- PLXNA4 | c.3882C>G p.A1294= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV58113888, COSV58135816; called by muse, mutect2, varscan2
- PPP1R3G | c.900C>T p.F300= | Silent (SNP) | VAF 112/631 reads (18%) | called by muse, mutect2, varscan2
- PPP1R8 | c.78T>C p.G26= | Silent (SNP) | VAF 11/131 reads (8%) | called by muse, mutect2
- PTS | c.273G>A p.K91= | Silent (SNP) | VAF 162/578 reads (28%) | catalogued as rs1318726823; called by muse, mutect2, varscan2
- RANBP9 | c.804A>G p.G268= | Silent (SNP) | VAF 28/108 reads (26%) | called by muse, mutect2, varscan2
- RBMXL1 | c.885A>T p.P295= | Silent (SNP) | VAF 161/492 reads (33%) | called by muse, mutect2, varscan2
- RYR1 | c.10122C>G p.S3374= | Silent (SNP) | VAF 43/566 reads (8%) | catalogued as COSV62099887; called by muse, mutect2
- SCN11A | c.1503G>T p.L501= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV100180966; called by muse, mutect2, varscan2
- SEMA7A | c.438C>T p.N146= | Silent (SNP) | VAF 55/208 reads (26%) | catalogued as rs200205962; called by muse, mutect2, varscan2
- SLC25A52 | c.744C>T p.R248= (on ENST00000672005; = p.R238= on NM_001034172.4) | Silent (SNP) | VAF 16/113 reads (14%) | called by muse, mutect2, varscan2
- SLC4A4 | c.2091T>C p.F697= (on ENST00000264485 / NM_001098484.3; = p.F653= on NM_003759.4) | Silent (SNP) | VAF 38/166 reads (23%) | called by muse, mutect2, varscan2
- SNAI2 | c.375T>A p.A125= | Silent (SNP) | VAF 143/497 reads (29%) | called by muse, mutect2, varscan2
- SOCS2 | c.45G>T p.G15= | Silent (SNP) | VAF 31/125 reads (25%) | called by muse, mutect2, varscan2
- SOX1 | c.825C>A p.G275= | Silent (SNP) | VAF 35/69 reads (51%) | called by muse, mutect2, varscan2
- SULT1A2 | c.174G>A p.L58= | Silent (SNP) | VAF 25/137 reads (18%) | called by muse, mutect2, varscan2
- SYNE1 | c.21795G>T p.L7265= (on ENST00000367255 / NM_182961.4; = p.L7194= on NM_033071.3) | Silent (SNP) | VAF 146/692 reads (21%) | called by muse, mutect2, varscan2
- SYNE2 | c.14250G>T p.L4750= | Silent (SNP) | VAF 275/727 reads (38%) | called by muse, mutect2, varscan2
- SYT10 | c.1512G>T p.R504= | Silent (SNP) | VAF 49/299 reads (16%) | called by muse, mutect2, varscan2
- TAFA2 | c.138G>A p.V46= | Silent (SNP) | VAF 47/434 reads (11%) | catalogued as COSV69184902; called by muse, mutect2, varscan2
- TBCEL | c.477C>T p.C159= | Silent (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- UBR3 | c.1023G>T p.V341= | Silent (SNP) | VAF 74/258 reads (29%) | called by muse, mutect2, varscan2
- UPF1 | c.1152G>C p.L384= (on ENST00000599848 / NM_001297549.2; = p.L373= on NM_002911.4) | Silent (SNP) | VAF 11/133 reads (8%) | called by muse, mutect2
- XYLB | c.273C>G p.A91= | Silent (SNP) | VAF 32/74 reads (43%) | called by muse, mutect2, varscan2
- ZNF526 | c.576C>T p.V192= | Silent (SNP) | VAF 291/433 reads (67%) | called by muse, mutect2, varscan2
- ZNF90 | c.1713C>T p.G571= | Silent (SNP) | VAF 36/378 reads (10%) | catalogued as rs534439133; called by muse, mutect2
- ABCC8 | c.*3T>A | 3'UTR (SNP) | VAF 101/698 reads (14%) | called by muse, mutect2, varscan2
- AC006288.1 | n.275C>A | RNA (SNP) | VAF 74/196 reads (38%) | called by muse, mutect2, varscan2
- AC093334.1 | n.122G>C | RNA (SNP) | VAF 30/82 reads (37%) | catalogued as rs372573581; called by muse, mutect2, varscan2
- AC244517.10 | c.36-9372G>A | Intron (SNP) | VAF 176/498 reads (35%) | called by muse, mutect2, varscan2
- AGPAT4 | c.843+2347G>T | Intron (SNP) | VAF 42/264 reads (16%) | catalogued as rs1430179589; called by muse, mutect2, varscan2
- AMN1 | c.171+345G>A | Intron (SNP) | VAF 5/29 reads (17%) | catalogued as rs983154675; called by muse, mutect2
- AP000769.5 | chr11:65498225 C>T | 5'Flank (SNP) | VAF 33/234 reads (14%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498669 C>A | 5'Flank (SNP) | VAF 16/121 reads (13%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500733 G>T | 5'Flank (SNP) | VAF 54/302 reads (18%) | catalogued as rs1409906757; called by muse, mutect2, varscan2
- ATPSCKMT | c.16+13C>A | Intron (SNP) | VAF 31/110 reads (28%) | catalogued as rs757259178; called by muse, mutect2, varscan2
- BANK1 | c.-17C>T | 5'UTR (SNP) | VAF 83/266 reads (31%) | catalogued as rs538462619; called by muse, mutect2, varscan2
- BHLHE22 | c.*2C>T | 3'UTR (SNP) | VAF 144/434 reads (33%) | called by muse, mutect2, varscan2
- C2CD5 | c.801-1009C>T | Intron (SNP) | VAF 49/262 reads (19%) | called by muse, mutect2, varscan2
- CDH8 | c.1536+58G>A | Intron (SNP) | VAF 22/72 reads (31%) | called by muse, mutect2, varscan2
- CFAP410 | c.*18C>T | 3'UTR (SNP) | VAF 83/255 reads (33%) | catalogued as rs773942752; called by muse, mutect2, varscan2
- CGB7 | c.-2254C>A | 5'UTR (SNP) | VAF 28/84 reads (33%) | called by muse, varscan2
- CHL1 | c.-29T>C | 5'UTR (SNP) | VAF 10/68 reads (15%) | called by mutect2, varscan2
- CHRD | c.983-19C>T | Intron (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- CHST15 | c.1347+37C>G | Intron (SNP) | VAF 75/182 reads (41%) | catalogued as COSV60566775; called by muse, mutect2, varscan2
- CNTNAP3P2 | n.947G>C | RNA (SNP) | VAF 84/520 reads (16%) | called by muse, mutect2, varscan2
- CSF1 | c.-87C>T | 5'UTR (SNP) | VAF 18/41 reads (44%) | catalogued as rs993689734, COSV100294320, COSV60034224; called by muse, mutect2, varscan2
- DCAF17 | c.*477G>A | 3'UTR (SNP) | VAF 48/154 reads (31%) | called by muse, mutect2, varscan2
- DLGAP3 | c.*147C>T | 3'UTR (SNP) | VAF 21/55 reads (38%) | catalogued as rs1483022724; called by muse, mutect2, varscan2
- DOCK10 | c.1685+25G>C | Intron (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- DVL1 | c.-3G>T | 5'UTR (SNP) | VAF 42/209 reads (20%) | called by muse, mutect2, varscan2
- FAM241B | c.-104+341T>C | Intron (SNP) | VAF 27/103 reads (26%) | called by muse, mutect2, varscan2
- FGD4 | c.-195A>T | 5'UTR (SNP) | VAF 48/297 reads (16%) | called by muse, mutect2, varscan2
- GRIA4 | c.487+44611C>A | Intron (SNP) | VAF 24/94 reads (26%) | called by muse, mutect2, varscan2
- GXYLT1 | c.-56C>T | 5'UTR (SNP) | VAF 15/114 reads (13%) | called by muse, mutect2, varscan2
- MAN1B1 | c.219+219T>C | Intron (SNP) | VAF 21/102 reads (21%) | called by muse, mutect2, varscan2
- MIR382 | n.20C>A | RNA (SNP) | VAF 36/281 reads (13%) | called by muse, mutect2, varscan2
- MTRNR2L1 | c.-2G>T | 5'UTR (SNP) | VAF 58/251 reads (23%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40561372 G>T | 5'Flank (SNP) | VAF 132/288 reads (46%) | called by muse, mutect2, varscan2
- MYL2 | c.354-38C>A | Intron (SNP) | VAF 234/731 reads (32%) | called by mutect2, varscan2
- NDUFA12 | c.170-2659G>T | Intron (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- NEB | c.11601+6154A>T | Intron (SNP) | VAF 112/1550 reads (7%) | called by muse, mutect2
- NOX5 | c.-14G>C | 5'UTR (SNP) | VAF 54/127 reads (43%) | called by muse, mutect2, varscan2
- NPEPPSP1 | n.166C>T | RNA (SNP) | VAF 90/226 reads (40%) | catalogued as rs1360179356; called by mutect2, varscan2
- OR2W5 | n.1042C>A | RNA (SNP) | VAF 24/346 reads (7%) | called by muse, mutect2
- PKD1L2 | n.729G>T | RNA (SNP) | VAF 12/36 reads (33%) | catalogued as rs1449343134; called by muse, varscan2
- RNASEH1 | c.-30C>G | 5'UTR (SNP) | VAF 8/27 reads (30%) | catalogued as rs774009217; called by muse, mutect2, varscan2
- SLC9A3 | c.*81A>C | 3'UTR (SNP) | VAF 38/116 reads (33%) | called by muse, mutect2
- SOX6 | c.*46C>T | 3'UTR (SNP) | VAF 13/76 reads (17%) | catalogued as rs758501223; called by muse, mutect2, varscan2
- SYT14 | c.*648A>T | 3'UTR (SNP) | VAF 26/166 reads (16%) | catalogued as rs1309073812; called by muse, varscan2
- TERB2 | c.65-26T>C | Intron (SNP) | VAF 129/326 reads (40%) | called by muse, mutect2, varscan2
- TRAV22 | chr14:22066337 G>A | 5'Flank (SNP) | VAF 57/127 reads (45%) | called by muse, mutect2, varscan2
- TRBV19 | c.-24C>G | 5'UTR (SNP) | VAF 97/199 reads (49%) | called by muse, mutect2, varscan2
- USP34 | chr2:61185835 C>G | 3'Flank (SNP) | VAF 16/99 reads (16%) | called by muse, mutect2, varscan2
- WDR59 | c.1866+4213del | Intron (DEL) | VAF 73/526 reads (14%) | called by mutect2, pindel, varscan2
- YY1AP1 | c.48-56C>A | Intron (SNP) | VAF 40/97 reads (41%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+4509T>A | Intron (SNP) | VAF 93/574 reads (16%) | called by muse, mutect2, varscan2
- ZNF292 | c.168+13934C>T | Intron (SNP) | VAF 40/339 reads (12%) | catalogued as rs755710227; called by muse, mutect2, varscan2
- ZNF397 | chr18:35254448 G>A | 3'Flank (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- ZNF783 | c.-71C>T | 5'UTR (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
